Surgical pathology report (de-identified scan), TCGA case TCGA-49-AAQV, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Johns Hopkins, specimen TCGA-49-AAQV-01A (Primary Tumor).

[page 1 of 8]
Spec. Taken

=====

INTERPRETATION AND DIAGNOSIS:

1. LYMPH NODE, L8 (EXCISION): ONE (1) LYMPH NODE AND ASSOCIATED FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.

2. LUNG (RESECTION):

SPECIMEN TYPE:
Lobectomy, left lower lobe

TUMOR SITE:
Left Lower lobe

HISTOLOGIC TYPE:
Adenocarcinoma (70% Acinar, 30% solid)

TUMOR SIZE:
2.3 cm

HISTOLOGIC GRADE:
G3: Poorly Differentiated

LYMPH NODES:
Metastatic carcinoma in 1 of 11 lymph nodes

EXTENT OF INVASION (7th Edition, AJCC): PRIMARY TUMOR:
pT1b: Tumor >2 cm but 3 cm of less

REGIONAL LYMPH NODES:
pN1: Metastasis in ipsilateral peribronchial, hilar,
or intrapulmonary nodes, including those
involved by direct extension

DISTANT METASTASIS:
pMx: Cannot be assessed

MARGINS:
Margins uninvolved by invasive carcinoma

VENOUS/ARTERIAL (LARGE VESSEL) INVASION:

(Continued on next page.)

ICD-O-3
Adenocarcinoma w/ mixed subtypes
(acinar & solid) 8255/3
Site @ Lung, lower lobe C34.3
JTS 6/24/14

[page 2 of 8]
=====

Absent

LYMPHATIC (SMALL VESSEL) INVASION:
Indeterminate

3. LYMPH NODE, STATION 6 (EXCISION): TWO (2) LYMPH NODES AND
ASSOCIATED FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.

4. LYMPH NODE, STATION 7 (EXCISION): ONE (1) LYMPH NODE AND
ASSOCIATED FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.

5. LYMPH NODE, L10 (EXCISION): ONE (1) LYMPH NODE AND ASSOCIATED
FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.

Note: A movat stain was reviewed. This case was shown at the
. KRAS, EGFR and ALK molecular analysis
have been ordered and will be reported in an addendum.

*Electronic signature

ADDENDUM:

RESULTS OF ALK FISH ANALYSIS: NEGATIVE

THIS RESULT SHOWED NO EVIDENCE OF REARRANGEMENT OF THE ALK GENE.

A COPY OF THE COMPLETE REPORT IS AVAILABLE IN AND IS ON FILE IN

*Electronic signature

(Continued on next page.)

[page 3 of 8]
ADDENDUM:

F

F

SOURCE:

TEST: EGFR MUTATION ANALYSIS
EGFR MUTATION ANALYSIS
Specimen Number:

Received Date:
Referring #:
ICD9 Code:

2SD	Tissue	Probe	Result	%pat
	Slides	EGFR	POSITIVE	

Consultant Date:
Consultant's Findings:

A c.2235_2249del (p.E746_A750del) mutation was detected in Exon 19 of the EGFR gene. This mutation is reported to correlate with RESPONSIVENESS to EGFR tyrosine kinase inhibitor therapies in patients with non-small-cell lung cancer.

Mutations in the tyrosine kinase domain of the epidermal

(Continued on next page.)

[page 4 of 8]
growth factor receptor (EGFR) gene are reported to be associated with differential responsiveness/resistance to targeted therapeutics for non-small-cell lung cancer (NSCLC).

Most data published pertain to Gefitinib . Similar data have been seen in studies using Erlotinib .

This test is validated for non-small cell lung carcinoma. The clinical significance and utility of this test in other tumor types is unknown.

Method: This assay analyzes exons 18-21 of the EGFR tyrosine kinase domain. Based on current literature, the vast majority of mutations are expected to occur in these exons. Tissue sections are reviewed by a pathologist and relevant tumor is selected for analysis. DNA is extracted from the tissue and subject to PCR amplification using primers to exons 18-21 of the EGFR gene. The amplification products are analyzed by bi-directional direct DNA sequencing using capillary gel electrophoresis and fluorescence detection. The analytical sensitivity of the assay is 20% mutant alleles, or 40% tumor cells with a heterozygous mutation; mutations present in a low percentage of cells may not be detected.

References:

Pao W and Miller VA. J Clin Oncol. 2005; 23:2556-2568.
Lynch TJ, et al. N Eng J Med. 2004; 350:2129-2139.
Paez JG, et al. Science. 2004; 304:1497-1500.
Sharma SV, et al. Nat Rev Cancer. 2007; 7:169-180.

This test was developed and its performance characteristics determined by . It has not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. This test is used for clinical purposes. It should not be regarded as investigational or for research.

COMMENT:

Interpretation and recommendation provided by:

(Continued on next page.)

[page 5 of 8]
Assistant Professor, Department of Pathology
Test performed by

*Electronic signature

Clinical History:

HISTORY OF PET POSITIVE LEFT LOWER LOBE LESION.

GROSS DESCRIPTION

PART #1: L 8 LYMPH NODE

Resident Pathologist:

Dictated by:

The specimen for Part 1 is received in formalin, labeled with the patient's name, [REDACTED] and designated 'L-8 Lymph Node.' The specimen consists of one (1) piece of red-tan-gray soft tissue measuring 1 x 0.8 x 0.5 cm. The specimen is submitted in its entirety.

SUMMARY OF SECTIONS:

1 - A - 1 (ENTIRETY OF SPECIMEN)
1 - TOTAL - 1

(Continued on next page.)

[page 6 of 8]
PART #2: LEFT LOWER LOBE
Resident Pathologist:

Dictated by:

The specimen for Part 2 is received in formalin, labeled with the patient's name, [REDACTED] and designated 'Left Lower Lobe.' The specimen consists of a 15.0 x 15.0 x 2.5 cm grossly recognizable lung lobe weighing 167.5 gm. The pleural surface is red-purple, wrinkled and glistening. A surgical incision is present over a grossly apparent mass which measures 2.3 x 2.0 x 1.5 cm. The pleural surface overlying this mass appears puckered. The pleural surface overlying the tumor mass is inked black. This tumor is located in the superior aspect of the lobe, approximately 1.8 cm from the bronchial margin. Three (3) staple lines are present on the lung measuring 6 cm, 4 cm and 2 cm. The first two (2) staple lines are removed to reveal underlying grossly unremarkable lung parenchyma which is inked orange. The third staple line contains vessels which are sectioned and submitted. A shave section of the bronchial margin is also taken. No grossly identifiable hilar lymph nodes are present. The tumor nodule is thoroughly serially sectioned to reveal that it abuts the pleura and is 0.4 cm from the surgical resection margin. The tumor mass appears to surround large vessels in the lung parenchyma. Representative sections of tumor relative to pleura, vessels, and surgical resection margin are submitted. Serially sectioning through the remaining lung tissue identified two (2) subpleural nodules which were suspicious for tumor involvement. Representative sections are submitted. No other masses or lesions are identified within the lung. The uninvolved lung parenchyma appears tan-red and grossly unremarkable. Representative sections of the uninvolved lung are submitted.

SUMMARY OF SECTIONS:

1 - A	- 1	(BRONCHIAL MARGIN)
1 - B	- 1	(VASCULAR MARGINS)
2 - C&D	- 1 EA	(TUMOR IN RELATION TO PLEURA AND VESSELS)
2 - E&F	- 1 EA	(TUMOR IN RELATION TO SURGICAL RESECTION MARGIN)
2 - G&H	- 1 EA	(SUBPLEURAL NODULES)
2 - I&J	- 1 EA	(REPRESENTATIVE SECTIONS OF UNINVOLVED LUNG)
12 - TOTAL	- 12	

(Continued on next page.)

[page 7 of 8]
=====

PART #3: STATION 6 LYMPH NODE

Resident Pathologist:

Dictated by:

The specimen for Part 3 is received in formalin, labeled with the patient's name, [REDACTED] and designated 'Station 6 Lymph Node.' The specimen consists of multiple pieces of red-tan-yellow soft tissue measuring 1.8 x 1.1 x 0.3 cm in aggregate. The specimen is submitted in its entirety.

SUMMARY OF SECTIONS:

1 - A - M (ENTIRETY OF SPECIMEN)
1 - TOTAL - MULTIPLE

PART #4: STATION 7 LYMPH NODE

Resident Pathologist:

Dictated by:

The specimen for Part 4 is received in formalin, labeled with the patient's name, [REDACTED] and designated 'Station 7 Lymph Node.' The specimen consists of one (1) piece of red-tan-brown soft tissue measuring 1.4 x 0.7 x 0.3 cm. The specimen is submitted in its entirety.

SUMMARY OF SECTIONS:

1 - A - 1 (ENTIRETY OF SPECIMEN)
1 - TOTAL - 1

(Continued on next page.)

[page 8 of 8]
PART #5: L 10 LYMPH NODE
Resident Pathologist:

Dictated by:

The specimen for Part 5 is received in formalin, labeled with the patient's name, [REDACTED] and designated 'L-10 Lymph Node.' The specimen consists of one (1) piece of red-tan-brown soft tissue measuring 1.4 x 1.2 x 0.4 cm.
One hundred percent (100%) of the specimen is submitted.

SUMMARY OF SECTIONS:

1 - A - 1 (ENTIRETY OF SPECIMEN)
1 - TOTAL - 1

Other Surgical Pathology Specimens known to the computer: [REDACTED]

(End of Report)

printed

Per TSS 70% acinar 30% solid

Source: NCI Genomic Data Commons file 79c453b8-dce2-4670-9fb5-ea0709ef7eeb (TCGA-49-AAQV.4FE4DC74-AF70-4F6C-B290-561808DD7FAE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).